Somatic mutation profile of tumor specimen TCGA-KM-8439-01A (aliquot TCGA-KM-8439-01A-11D-2310-10) from TCGA case TCGA-KM-8439, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 30.8 years (11,266 days).
Specimen TCGA-KM-8439-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3cb33b9a-d2a4-4c09-aedd-03d7d6e53179.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8439-10A (Blood Derived Normal), aliquot TCGA-KM-8439-10A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f32a61b-e490-4165-93a4-c20265e104cb

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DUSP11 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as rs574278061, COSV55594055; called by muse, mutect2, varscan2
- LAMA3 | c.2509G>T p.D837Y | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV100555596, COSV100557400, COSV58075359; called by muse, mutect2
- TUB | c.1039G>A p.G347R (on ENST00000299506 / NM_177972.3; = p.G402R on NM_003320.4) | Missense Mutation (SNP) | VAF 7/194 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100210039; called by muse, mutect2
- ZNF629 | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1479156326, COSV99354877, COSV99354913; called by muse, mutect2, varscan2
- EYA4 | c.920C>A p.T307N | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GDF5 | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCMF1 | c.314del p.S105* | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- SELENOI | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WNT3 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GP6 | c.-16A>G | 5'UTR (SNP) | VAF 4/39 reads (10%) | catalogued as COSV100117405; called by muse, mutect2, varscan2
